Gene-level copy-number profile of tumor specimen TCGA-22-5471-01A from TCGA case TCGA-22-5471, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.0 years (27,749 days).
Specimen TCGA-22-5471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.83956a99-0aad-403b-a738-03b66429d01c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5471-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0edef4b8-515d-4e8c-a48f-ea5865718b0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 1,107; copy number 2: 15,728; copy number 3: 26,648; copy number 4: 7,711; copy number 5: 4,295; copy number 6: 1,619; copy number 7: 402; copy number 8: 79; copy number 9: 213; copy number 10: 116; copy number 11: 1,080; copy number 13: 200; copy number 15: 122; copy number 17: 212; copy number 20: 5; copy number 21: 102; copy number 22: 33; copy number 28: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5471-01A-01D-1631-01): tumor purity 0.44, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–31,254,777, 132 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,574 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–121,580,524, 80 genes, copy number 7 (broad region; genes not listed).
- chr2:33,706,886–39,124,345, 85 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:45,388,680–46,859,007, 25 genes, copy number 7 (within-gene range 5–7): SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119.
- chr3:146,909,685–163,361,563, 275 genes, copy number 9–11 (within-gene range 3–11) (broad region; genes not listed).
- chr3:164,670,878–198,222,513, 636 genes, copy number 8–17 (broad region; genes not listed).
- chr8:120,380,761–127,742,951, 125 genes, copy number 7–28 (within-gene range 3–28) (broad region; genes not listed).
- chr8:127,795,962–127,796,028, 1 gene, copy number 20: MIR1204.
- chr10:26,379,034–33,390,935, 148 genes, copy number 7–13 (broad region; genes not listed).
- chr11:44,973,770–46,929,320, 58 genes, copy number 17: LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1.
- chr11:69,048,932–70,436,584, 42 genes, copy number 8–22: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 22: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr12:1,970,786–2,697,950, 1 gene, copy number 10 (within-gene range 3–10): CACNA1C.
- chr12:2,217,462–32,396,147, 769 genes, copy number 10–11 (broad region; genes not listed).
- chr12:32,477,382–32,477,471, 1 gene, copy number 11: RNU6-494P.
- chr18:22,347,846–44,071,701, 265 genes, copy number 10–21 (broad region; genes not listed).
- chr20:35,201,745–36,646,196, 57 genes, copy number 8 (within-gene range 3–8): MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2.

Autosomal genes at a single copy (total copy number 1): 1,107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
